Somatic mutation profile of tumor specimen TCGA-N6-A4VD-01A (aliquot TCGA-N6-A4VD-01A-11D-A28R-08) from TCGA case TCGA-N6-A4VD, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Age at diagnosis: 81.2 years (29,658 days).
Specimen TCGA-N6-A4VD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3f90e71-9fb9-4812-a991-cdc65fd095dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N6-A4VD-11A (Solid Tissue Normal), aliquot TCGA-N6-A4VD-11A-11D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20daa18b-a2f8-47b0-85aa-73490de7c363

The open-access MAF lists 100 somatic variants for this specimen: 76 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 22, Nonsense Mutation 4, Frame Shift Del 4, Frame Shift Ins 2, Intron 2, In Frame Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 46/55 reads (84%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs1555791268, COSV59042459, COSV59042650; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 42/46 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060500126, CM032998, COSV64291751, COSV64292375; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- SLC35A2 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs587776961, CM132547; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- STAT3 | c.1152T>G p.F384L | Missense Mutation (SNP) | VAF 36/76 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as CM086679, CM141696, COSV52891290; called by muse, mutect2, varscan2
- ACSF3 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs376098216, COSV58080991; called by muse, mutect2, varscan2
- ADAM12 | c.2449C>T p.R817* | Nonsense Mutation (SNP) | VAF 34/79 reads (43%) | catalogued as rs769115498, COSV64133210; called by muse, mutect2, varscan2
- ADAT3 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs776872856; called by muse, varscan2
- ADCY6 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs758994257, COSV100326363; called by muse, mutect2, varscan2
- AFF3 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs546235334; called by muse, mutect2
- ALS2CL | c.2668G>A p.V890M | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420355279, COSV59671837, COSV59671997; called by muse, mutect2, varscan2
- APOB | c.2635G>A p.V879M | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.092); catalogued as rs564030306, COSV51932879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF25 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs542655828, COSV54089457; called by muse, mutect2, varscan2
- CCDC148 | c.71A>G p.Y24C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752520073; called by muse, mutect2, varscan2
- CCR6 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.233); catalogued as rs545727839; called by muse, mutect2, varscan2
- CDC42EP2 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.091); catalogued as rs763526695; called by muse, mutect2, varscan2
- CHM | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.058); catalogued as rs569919713, COSV63305380; called by muse, mutect2, varscan2
- CHST12 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs1486326455, COSV99324664; called by muse, mutect2, varscan2
- CIC | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as rs749708777, COSV50598916; called by muse, mutect2, varscan2
- DMBT1 | c.5965C>T p.R1989* (on ENST00000338354 / NM_001377530.1; = p.R1232* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 45/54 reads (83%) | catalogued as rs143073434, COSV100353895; called by muse, mutect2, varscan2
- EPG5 | c.7334G>A p.R2445Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs756772032, COSV56351301, COSV56352007; called by muse, mutect2, varscan2
- EPS8L1 | c.1174G>A p.E392K (on ENST00000201647 / NM_133180.3; = p.E265K on NM_017729.3) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs755923265; called by muse, mutect2, varscan2
- FBXO24 | c.265C>T p.R89C (on ENST00000241071 / NM_033506.3; = p.R127C on NM_012172.5) | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.549); catalogued as rs563719782, COSV53823656; called by muse, mutect2, varscan2
- FLNA | c.6416G>A p.R2139Q (on ENST00000369850 / NM_001110556.2; = p.R2131Q on NM_001456.3) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV100774603; called by muse, mutect2, varscan2
- FLT1 | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.708); catalogued as rs753953796; called by muse, mutect2, varscan2
- FMN2 | c.3508G>A p.G1170R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.692); catalogued as rs773685058, COSV60444898; called by muse, mutect2, varscan2
- GLB1L3 | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775360870, COSV101111086, COSV66280968; called by muse, mutect2
- GSTA3 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99274713; called by muse, mutect2, varscan2
- HERPUD2 | c.816C>A p.F272L | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100257796; called by muse, mutect2, varscan2
- KCNS2 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs781697576, COSV54637693; called by muse, mutect2, varscan2
- KIAA1217 | c.2437G>A p.V813I | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs560634485, COSV56818111; called by muse, mutect2, varscan2
- MAB21L4 | c.850C>T p.R284C (on ENST00000388934 / NM_001085437.3; = p.R116C on NM_024861.4) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs767515550, COSV100278765; called by muse, mutect2, varscan2
- MAGEB6 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs376873999; called by muse, mutect2, varscan2
- MRGPRX3 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs141255495; called by muse, mutect2, varscan2
- NLRP5 | c.3352C>T p.L1118F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1469465828, COSV66765061; called by muse, mutect2
- OR52I2 | c.770G>A p.G257D | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs750606405, COSV57044174; called by muse, mutect2, varscan2
- PLEKHA2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs569997545; called by muse, mutect2, varscan2
- PLK3 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs370347467; called by muse, mutect2, varscan2
- PLXNB2 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63784930; called by muse, mutect2, varscan2
- PLXNB3 | c.3445C>T p.R1149C | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.608); catalogued as rs782820984, COSV100738109; called by muse, mutect2, varscan2
- RHBDL3 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as rs748181433; called by muse, mutect2, varscan2
- RHOXF1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782789749; called by muse, mutect2, varscan2
- RPS6KC1 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65296802; called by muse, mutect2, varscan2
- RRAGB | c.430C>T p.R144* (on ENST00000262850 / NM_016656.4; = p.R116* on NM_006064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as rs376938151, COSV99469186; called by muse, mutect2, varscan2
- TMEM62 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs1270741636, COSV53042257, COSV99543691; called by muse, mutect2, varscan2
- TPO | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 34/75 reads (45%) | catalogued as rs763459820, CM076569, COSV61093527; called by muse, mutect2, varscan2
- AFF2 | c.1222C>A p.P408T | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCORL1 | c.2847del p.P950Lfs*25 | Frame Shift Del (DEL) | VAF 35/122 reads (29%) | called by mutect2, pindel, varscan2
- BCORL1 | c.5060_5061del p.V1687Gfs*57 | Frame Shift Del (DEL) | VAF 23/92 reads (25%) | called by pindel, varscan2
- BFAR | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CYLC1 | c.1120T>A p.S374T | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- DGKZ | c.791del p.P264Rfs*44 (on ENST00000454345 / NM_001105540.2; = p.P75Rfs*44 on NM_003646.4) | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | called by mutect2, pindel, varscan2
- EXOC4 | c.2644A>G p.T882A | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- FCRL4 | c.1249+1G>A p.X417_splice | Splice Site (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- FGD6 | c.2975C>T p.A992V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- FTH1 | c.492_500del p.G165_A167del | In Frame Del (DEL) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- GPRASP1 | c.764A>C p.D255A | Missense Mutation (SNP) | VAF 7/193 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2
- IARS2 | c.1493dup p.V499Gfs*14 | Frame Shift Ins (INS) | VAF 18/76 reads (24%) | called by mutect2, pindel, varscan2
- IGHG4 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ITIH3 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- MPRIP | c.2609C>T p.A870V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- NET1 | c.880_882del p.L294del (on ENST00000355029 / NM_001047160.3; = p.L240del on NM_005863.5) | In Frame Del (DEL) | VAF 21/46 reads (46%) | called by mutect2, pindel, varscan2
- OR4C6 | c.54C>G p.N18K | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- PCDHA2 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 163/287 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- REG3G | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SCN5A | c.4885_4886insATCCTCAGACT p.R1629Hfs*6 (on ENST00000333535 / NM_198056.3; = p.R1628Hfs*6 on NM_000335.5) | Frame Shift Ins (INS) | VAF 43/130 reads (33%) | called by mutect2, pindel*, varscan2*
- SLC16A2 | c.893C>A p.T298N | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC28A3 | c.1799T>C p.V600A | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SMOC1 | c.11C>A p.A4E | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SOGA3 | c.1273_1274del p.Q425Dfs*29 | Frame Shift Del (DEL) | VAF 27/84 reads (32%) | called by mutect2, pindel, varscan2
- STK16 | c.651T>A p.D217E | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SUV39H1 | c.605A>C p.K202T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TAB3 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE2NL | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- ZNF655 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- AFF3 | c.1173T>A p.A391= | Silent (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2
- CALCR | c.1047G>A p.A349= (on ENST00000649521 / NM_001164737.2; = p.A333= on NM_001742.4) | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs545295161; called by muse, mutect2, varscan2
- CDH26 | c.1437G>T p.P479= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV54844721; called by muse, mutect2, varscan2
- CDX2 | c.780G>A p.P260= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as COSV66829437; called by muse, mutect2, varscan2
- CSMD3 | c.10407T>C p.G3469= (on ENST00000297405 / NM_001363185.1; = p.G3300= on NM_052900.3) | Silent (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.1851G>A p.S617= (on ENST00000450689 / NM_001142749.3; = p.S450= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs369087183; called by muse, mutect2, varscan2
- EXOC3L1 | c.1728C>T p.R576= | Silent (SNP) | VAF 55/110 reads (50%) | catalogued as COSV52046386; called by muse, mutect2, varscan2
- FYB2 | c.1689G>A p.S563= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs140363025; called by muse, mutect2, varscan2
- H2AC16 | c.15C>T p.G5= | Silent (SNP) | VAF 51/132 reads (39%) | called by muse, mutect2, varscan2
- KIRREL3 | c.1521C>T p.S507= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs753433027, COSV101375240, COSV69384049; called by muse, mutect2, varscan2
- NSF | c.1428G>A p.T476= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs1162352524; called by muse, mutect2, varscan2
- OCEL1 | c.555T>C p.C185= | Silent (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- PCDHB5 | c.12G>A p.A4= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as rs782585460; called by muse, mutect2, varscan2
- PDGFRB | c.3018C>T p.S1006= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs2229559; called by muse, mutect2, varscan2
- PGS1 | c.639C>T p.N213= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as rs757502981, COSV53147860, COSV53147975; called by muse, mutect2, varscan2
- PHOSPHO2 | c.159G>A p.K53= | Silent (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- SLC6A9 | c.690C>T p.A230= (on ENST00000360584 / NM_201649.4; = p.A176= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as rs200658319; called by muse, mutect2, varscan2
- SPIRE2 | c.1060C>A p.R354= | Silent (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- SPTA1 | c.3585G>A p.T1195= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as rs755030250, COSV63748653; called by muse, mutect2
- STK10 | c.1902C>T p.R634= | Silent (SNP) | VAF 53/164 reads (32%) | called by muse, mutect2, varscan2
- TBC1D1 | c.3426G>A p.T1142= | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as rs375379532; called by muse, mutect2, varscan2
- ZFHX4 | c.7635G>A p.P2545= | Silent (SNP) | VAF 49/136 reads (36%) | catalogued as rs781479742, COSV50970890; called by muse, mutect2, varscan2
- AOPEP | c.*5-1204G>A | Intron (SNP) | VAF 9/25 reads (36%) | catalogued as COSV99950868; called by muse, mutect2, varscan2
- NRG1 | c.502+30931G>A | Intron (SNP) | VAF 19/54 reads (35%) | catalogued as rs750558927, COSV99827170, COSV99829337; called by muse, mutect2, varscan2
